MMRF case MMRF_1383 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/032ca0da-a89e-43fe-bcb0-e0802c9c24d5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 73.6 years (26,900 days); ISS stage: I; Days to last known disease status: 1,415 days (3.9 years); Days to last follow up: 1,415 days (3.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 135 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 56 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 57 days; Days to treatment end: 135 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 167 days; Days to treatment end: 167 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 169 days; Days to treatment end: 169 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 276 days; Days to treatment end: 1,009 days (2.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 1.2 g/dL; Immunoglobulin G 18.4 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.86 µg/mL; Hemoglobin 7.44 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.1 mmol/L; Albumin 35 g/L; Total Protein 7.9 g/dL; Glucose 5.39 mmol/L.
- Day 85 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.662 mg/dL; Immunoglobulin G 6.76 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.15 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 5.17 mmol/L.
- Day 185 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.273 mg/dL; Immunoglobulin G 6.35 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 4.6 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 89 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.15 mmol/L; Albumin 32 g/L; Total Protein 6.5 g/dL; Glucose 6.22 mmol/L.
- Day 276 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Hemoglobin 9.11 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 4.4 mmol/L.
- Day 360 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.611 mg/dL; Hemoglobin 8.93 mmol/L; Leukocytes 3.9 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 7.04 mmol/L.
- Day 449 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.632 mg/dL; Hemoglobin 8.93 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 4.57 mmol/L.
- Day 505 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.845 mg/dL; Hemoglobin 8.74 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 4.79 mmol/L.
- Day 617 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.156 mg/dL; Hemoglobin 9.42 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 7.59 mmol/L.
- Day 729 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.675 mg/dL; Hemoglobin 9.42 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 3.96 mmol/L.
- Day 785 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Hemoglobin 9.86 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7.6 g/dL; Glucose 6.38 mmol/L.
- Day 897 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.633 mg/dL; Hemoglobin 9.3 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7.6 g/dL; Glucose 4.95 mmol/L.
- Day 1,009 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.871 mg/dL; Hemoglobin 9.36 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7.5 g/dL; Glucose 6.33 mmol/L.
- Day 1,065 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.811 mg/dL; Hemoglobin 8.99 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7.6 g/dL; Glucose 5.34 mmol/L.
- Day 1,191 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.791 mg/dL; Hemoglobin 9.36 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.08 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 5.34 mmol/L.
- Day 1,249 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Hemoglobin 9.11 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 7.3 g/dL; Glucose 6.6 mmol/L.
- Day 1,361 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 9.55 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 7.15 mmol/L.
- Day 1,415 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 52.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.841 mg/dL; Hemoglobin 9.55 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 5.78 mmol/L.

Other clinical attributes
- Day 1: Weight: 72 kg; Height: 167 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1383_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1383_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
